Gene-level copy-number profile of specimen HCM-SANG-0291-C15-85A from HCMI case HCM-SANG-0291-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G1.
Specimen HCM-SANG-0291-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b3df981-693e-443e-99b3-a8a5a4eef136.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0291-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/eaaf95a1-aa3b-4017-8590-81f0ac691c04

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,787; copy number 2: 45,051; copy number 3: 2,736; copy number 4: 114; copy number 5: 15; copy number 6: 23; copy number 8: 2; copy number 9: 30; copy number 10: 25; copy number 11: 4; copy number 15: 47; copy number 19: 67; copy number 26: 2; copy number 34: 5; copy number 35: 6; copy number 38: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 227 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:10,723,768–12,004,082, 47 genes, copy number 15: SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3, DEFB131E.
- chr8:33,226,848–33,600,023, 14 genes, copy number 6: AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr17:39,401,793–41,930,542, 162 genes, copy number 5–38 (within-gene range 4–38) (broad region; genes not listed).
- chr21:32,772,100–32,955,437, 1 gene, copy number 11 (within-gene range 1–11): C21orf62-AS1.
- chr21:32,841,496–32,849,934, 3 genes, copy number 11: AP000281.1, SNORA70, AP000281.2.

Autosomal genes at a single copy (total copy number 1): 7,931. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
